Somatic mutation profile of tumor specimen C3N-01071-03 (aliquot CPT0070060006) from CPTAC case C3N-01071, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.8 years (17,831 days).
Specimen C3N-01071-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08421ea8-16a5-4656-8473-460245cf26d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01071-71 (Blood Derived Normal), aliquot CPT0070160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82aa392-205c-4bf4-8f4e-a1c6bf324ec5

The open-access MAF lists 392 somatic variants for this specimen: 262 protein-altering or splice-affecting, 92 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 92, Intron 22, Nonsense Mutation 17, Splice Site 10, 5'Flank 4, RNA 4, 5'UTR 3, 3'UTR 3, Frame Shift Del 2, Translation Start Site 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 114/758 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCG5 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 59/455 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs368800131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABRA | c.1057C>A p.R353S | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61731865; called by muse, mutect2, varscan2
- APLP2 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99599422; called by muse, mutect2, varscan2
- BCHE | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as CM921036, CM990286, COSV52257220, COSV52262417; called by muse, mutect2, varscan2
- BTNL8 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176477871; called by muse, mutect2, varscan2
- CCDC154 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV101209720; called by muse, mutect2, varscan2
- CCDC66 | c.365G>C p.R122T (on ENST00000394672 / NM_001353147.1; = p.R88T on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1211874745; called by muse, mutect2
- CEMIP | c.2886C>A p.D962E | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54989265; called by muse, mutect2, varscan2
- CEP295 | c.6854C>G p.S2285* | Nonsense Mutation (SNP) | VAF 33/182 reads (18%) | catalogued as COSV57347953; called by muse, mutect2, varscan2
- CFAP54 | c.4939A>G p.T1647A | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV61574574; called by muse, mutect2
- CITED2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as rs1249578479; called by muse, mutect2
- CNOT1 | c.6676G>C p.A2226P | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55322328; called by muse, mutect2
- CPN1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 27/466 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV64942411; called by muse, mutect2
- CRISPLD1 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417819504; called by muse, mutect2
- CSN1S1 | c.105+1G>T p.X35_splice | Splice Site (SNP) | VAF 15/124 reads (12%) | catalogued as rs899897981, COSV99886971; called by muse, mutect2, varscan2
- CT47B1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 140/528 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV64891057; called by muse, mutect2, varscan2
- DDX60L | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV52716586; called by muse, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2
- DRP2 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65811664; called by muse, mutect2
- EVX1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs1472838364; called by muse, mutect2, varscan2
- FAT2 | c.11909A>G p.Y3970C | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1206094709; called by muse, mutect2
- FBXL7 | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.44); catalogued as COSV100309042, COSV61647922; called by muse, mutect2, varscan2
- FCF1 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs1205546594; called by muse, mutect2, varscan2
- GFRAL | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61234160; called by muse, mutect2
- GPR15 | c.615T>A p.F205L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV52520161; called by muse, mutect2, varscan2
- GRM1 | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51214642; called by muse, mutect2
- GRM7 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1181595820; called by muse, mutect2, varscan2
- HMCN2 | c.11179G>A p.D3727N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.672); catalogued as rs1300566429, COSV52983870; called by muse, mutect2, varscan2
- IGHV3-43 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); catalogued as rs573684200; called by muse, mutect2
- IQGAP2 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99167889; called by muse, mutect2, varscan2
- KIF2B | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as rs771221325, COSV52130217; called by muse, mutect2, varscan2
- KRT20 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs755778184; called by muse, mutect2, varscan2
- LGR5 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs563246260; called by muse, mutect2, varscan2
- LPIN3 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as rs1193212744; called by muse, mutect2
- LRFN1 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as COSV99952652; called by muse, mutect2, varscan2
- MSL2 | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 63/715 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53867109; called by muse, mutect2
- MUC16 | c.2689G>T p.V897L | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as rs371283786; called by muse, mutect2, varscan2
- MYH1 | c.5585G>T p.R1862L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs770764395, COSV56849278; called by muse, mutect2, varscan2
- NELL1 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54241744, COSV54295117; called by muse, mutect2, varscan2
- NF1 | c.6819G>C p.K2273N (on ENST00000358273 / NM_001042492.3; = p.K2252N on NM_000267.3) | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV62193968; called by muse, mutect2
- NLRP11 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs763042302; called by muse, mutect2, varscan2
- NOTCH2 | c.4252C>T p.P1418S | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56691208, COSV99868020; called by muse, mutect2
- NRP1 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55179206; called by muse, mutect2, varscan2
- NRXN2 | c.2044G>C p.V682L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV55448163; called by muse, mutect2, varscan2
- OR2M5 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs752271290; called by muse, mutect2
- OR5K4 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs966876742, COSV61583570; called by muse, mutect2, varscan2
- PAK5 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV62024978; called by muse, mutect2
- PCDHB6 | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 183/936 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99169997; called by muse, mutect2, varscan2
- PCLO | c.3944A>G p.K1315R | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61621765; called by muse, varscan2
- PLXNA1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 79/548 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1379909923; called by muse, mutect2, varscan2
- POM121L12 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV101374952; called by muse, varscan2
- PPFIA2 | c.2262G>A p.K754= | Splice Region (SNP) | VAF 20/132 reads (15%) | catalogued as COSV100335607; called by muse, mutect2, varscan2
- PPP1R2B | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.155); catalogued as rs4872; called by muse, mutect2, varscan2
- RBMXL3 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV57750205; called by muse, mutect2, varscan2
- ROS1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV63858244; called by muse, mutect2
- RPL29 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV53686429; called by muse, mutect2
- RPRD2 | c.4048G>A p.G1350R | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.04); catalogued as rs770483785, COSV64818724; called by muse, mutect2, varscan2
- RPS6KA2 | c.2140G>C p.V714L | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs890556346, COSV99071828; called by muse, mutect2
- RYR2 | c.14440A>G p.M4814V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as rs397516516; ClinVar: uncertain significance; called by muse, mutect2
- SETD1A | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as COSV52684600; called by muse, mutect2
- SHC3 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV101011930, COSV101011973; called by muse, mutect2, varscan2
- SI | c.1480C>A p.H494N | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV52297842; called by muse, mutect2, varscan2
- SLC36A1 | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54652366, COSV99695435; called by muse, mutect2, varscan2
- SLC5A4 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV56674540; called by muse, mutect2, varscan2
- SLCO5A1 | c.923T>C p.M308T | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as rs1450064645, COSV52667102; called by muse, mutect2
- SMARCA4 | c.4693G>T p.E1565* | Nonsense Mutation (SNP) | VAF 67/474 reads (14%) | catalogued as COSV60800087; called by muse, mutect2, varscan2
- SMARCB1 | c.890C>T p.T297M (on ENST00000263121; = p.T343M on NM_003073.5) | Missense Mutation (SNP) | VAF 34/1148 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.689); catalogued as rs773457718; ClinVar: uncertain significance; called by muse, mutect2
- SMPX | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as rs912201362; called by muse, mutect2, varscan2
- SORCS3 | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV63793517, COSV63799137; called by muse, mutect2
- SRCAP | c.5282G>C p.G1761A | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.069); catalogued as rs767130314; called by muse, mutect2, varscan2
- ST3GAL5 | c.206+1G>C p.X69_splice | Splice Site (SNP) | VAF 46/331 reads (14%) | catalogued as COSV60386937; called by muse, mutect2, varscan2
- TECRL | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV67089306; called by muse, mutect2, varscan2
- TRMT1L | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs764115207; called by muse, varscan2
- TRPS1 | c.412G>A p.D138N (on ENST00000220888 / NM_001330599.2; = p.D151N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV55228445; called by muse, mutect2
- UAP1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1445166906; called by muse, mutect2
- UGT3A1 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 19/344 reads (6%) | catalogued as rs1312995304; called by muse, mutect2
- USH2A | c.4619A>G p.D1540G | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.782); catalogued as COSV56448132; called by muse, mutect2, varscan2
- VANGL1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 34/602 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs751585191; called by muse, mutect2
- VAPA | c.128C>G p.S43W | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100486148, COSV61298468; called by muse, mutect2
- ZFHX4 | c.10419G>T p.E3473D | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV51500113; called by muse, mutect2
- A4GNT | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC9 | c.4546G>C p.V1516L | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ACOT2 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ACTR3C | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ADAM19 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ADAM2 | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ADPGK | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2
- AFAP1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARHGAP35 | c.3500G>T p.R1167L | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ARID1B | c.2797G>T p.A933S | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2
- ARR3 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- ATG10 | c.565_566del p.I189Hfs*27 | Frame Shift Del (DEL) | VAF 27/182 reads (15%) | called by pindel, varscan2
- ATP1A4 | c.2935G>T p.G979C | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2
- ATP7A | c.2150T>G p.F717C | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BICRA | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- BIRC6 | c.3766G>A p.G1256S | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2
- BMX | c.40A>T p.R14* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- C17orf78 | c.588T>A p.S196R | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C3 | c.412A>C p.I138L | Missense Mutation (SNP) | VAF 73/768 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.209); called by muse, mutect2
- C4orf17 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1C | c.4933C>T p.Q1645* | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- CALCR | c.912-2A>T p.X304_splice (on ENST00000649521 / NM_001164737.2; = p.X288_splice on NM_001742.4) | Splice Site (SNP) | VAF 34/240 reads (14%) | called by muse, mutect2, varscan2
- CD163 | c.1043A>T p.H348L | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2
- CDC25B | c.1218C>G p.D406E (on ENST00000245960 / NM_021873.3; = p.D392E on NM_004358.4) | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2
- CDH9 | c.1856T>A p.I619N | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CDHR3 | c.1033T>G p.C345G | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP350 | c.7922A>G p.Q2641R | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CFAP300 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, varscan2
- CLN3 | c.1150G>T p.A384S (on ENST00000360019 / NM_001286104.2; = p.A408S on NM_000086.2) | Missense Mutation (SNP) | VAF 61/529 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CLNK | c.631-2A>T p.X211_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- CMYA5 | c.4811G>T p.G1604V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CNTN4 | c.55+1G>T p.X19_splice | Splice Site (SNP) | VAF 20/479 reads (4%) | called by muse, mutect2
- COBL | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2
- CPNE2 | c.361-1G>T p.X121_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- CRB2 | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CSMD1 | c.3188G>T p.G1063V (on ENST00000520002; = p.G1062V on NM_033225.6) | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.7579T>A p.S2527T (on ENST00000297405 / NM_001363185.1; = p.S2423T on NM_052900.3) | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CSMD3 | c.2113C>G p.Q705E (on ENST00000297405 / NM_001363185.1; = p.Q601E on NM_052900.3) | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CYB5D2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- CYLD | c.1315T>C p.S439P | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP2A6 | c.1108T>G p.L370V | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCSTAMP | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DCTN4 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DHX29 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | called by muse, varscan2
- ELOVL6 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); called by muse, mutect2
- EVPL | c.3232G>C p.E1078Q | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- F5 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 38/541 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2
- FAM71B | c.1732C>A p.Q578K | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGFRL1 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXD4 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 77/1391 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FOXF2 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, varscan2
- FREM3 | c.2120C>A p.P707Q | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FUBP1 | c.1862A>T p.Q621L | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- FZD7 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GAS7 | c.715G>T p.E239* (on ENST00000432992 / NM_201433.2; = p.E99* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- GCK | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 142/663 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEMIN5 | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GLI2 | c.2427C>G p.I809M (on ENST00000361492 / NM_001374353.1; = p.I826M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLRA2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GLYATL3 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLM1 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2
- GOPC | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/118 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- GPC5 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HCN1 | c.942T>A p.C314* | Nonsense Mutation (SNP) | VAF 20/406 reads (5%) | called by muse, mutect2
- HIC1 | c.917C>T p.P306L (on ENST00000322941 / NM_001098202.1; = p.P287L on NM_006497.4) | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMCN1 | c.4589C>T p.A1530V | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGSF3 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- INSYN2B | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ITGA11 | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KCNK7 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 59/361 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ3 | c.583A>T p.R195W | Missense Mutation (SNP) | VAF 143/627 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF2B | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- KLHL22 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 19/428 reads (4%) | called by muse, mutect2
- KLHL24 | c.1193G>A p.W398* | Nonsense Mutation (SNP) | VAF 9/218 reads (4%) | called by muse, mutect2
- LAMA1 | c.3169G>T p.D1057Y | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LAMA4 | c.2363T>C p.L788P (on ENST00000230538 / NM_001105206.3; = p.L781P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/464 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMX1B | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRP1B | c.11799T>A p.D3933E | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MAEA | c.1186A>C p.M396L (on ENST00000303400 / NM_001017405.3; = p.M355L on NM_005882.5) | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- MAPK12 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK4 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MDN1 | c.11991G>T p.Q3997H | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); called by muse, mutect2
- MFSD6 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP15 | c.1927A>T p.T643S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- MORC1 | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, varscan2
- MRPS9 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2
- MTUS2 | c.1324A>T p.N442Y | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCBP2 | c.3506A>T p.D1169V (on ENST00000357337; = p.D1207V on NM_015057.5) | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- MYOZ2 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NAT16 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NAV2 | c.5074G>C p.E1692Q (on ENST00000396087 / NM_001244963.2; = p.E1636Q on NM_145117.5) | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NBAS | c.6188A>T p.K2063M | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- NCAM2 | c.1493G>C p.S498T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- NCBP1 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2
- NEK7 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NLGN4X | c.2202G>T p.M734I | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPHP4 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NR2F6 | c.939C>A p.P313= | Splice Region (SNP) | VAF 19/240 reads (8%) | called by muse, mutect2
- NR2F6 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- NR4A2 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.334); called by mutect2, varscan2
- NRG1 | c.1736A>G p.D579G (on ENST00000405005 / NM_013964.5; = p.D584G on NM_013956.5) | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN3 | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.536); called by muse, mutect2
- NUGGC | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- NUPR2 | c.-13_31del | Translation Start Site (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel
- OR2M4 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR5K2 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOG | c.1509G>A p.W503* | Nonsense Mutation (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- OTOP3 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PBXIP1 | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.59); called by muse, mutect2
- PCDH10 | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH9 | c.1640A>T p.N547I | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCGF3 | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2
- PCSK2 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 52/492 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PDCD4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PKHD1L1 | c.3047C>T p.T1016I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- PKHD1L1 | c.6065C>A p.T2022N | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PRB2 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- RALGAPA2 | c.5495+2T>C p.X1832_splice | Splice Site (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- RBM10 | c.1419_1420insT p.D474* | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- REPIN1 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- RFPL4A | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 147/1341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RFX6 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RIPOR3 | c.1811T>A p.L604Q | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- RNASEH2B | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- RNF133 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RNF185 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- RP1 | c.1453T>A p.Y485N | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- RRM1 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RTTN | c.202_219+8del p.X68_splice | Splice Site (DEL) | VAF 12/146 reads (8%) | called by mutect2, pindel
- SEC11A | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2
- SEMA4D | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SF3B4 | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLC35F3 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC44A4 | c.887C>A p.T296N | Missense Mutation (SNP) | VAF 110/568 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLCO1C1 | c.85T>A p.Y29N | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK6 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SMARCA5 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SNPH | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA48 | c.355T>G p.L119V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPO11 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SPRED1 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPSB4 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- STX18 | c.169-1G>C p.X57_splice | Splice Site (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- TACR3 | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF6 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TAMALIN | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2
- TAS2R10 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TATDN2 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2
- TBX2 | c.482A>T p.D161V | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBXT | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 26/782 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEX15 | c.3527C>T p.S1176F (on ENST00000256246; = p.S1559F on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2
- TGFBRAP1 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- THOC1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2
- TMEM250 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMEM64 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TMEM71 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- TMTC1 | c.1823G>T p.G608V (on ENST00000539277 / NM_001193451.2; = p.G500V on NM_175861.3) | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, varscan2
- TSPAN18 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPOAP1 | c.2828C>G p.A943G | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- TUT4 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.386); called by muse, varscan2
- UBQLNL | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBR2 | c.2728G>T p.E910* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- UIMC1 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- UNC5C | c.2378T>C p.L793P | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- USH2A | c.14894T>A p.V4965E | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.299); called by muse, mutect2
- USP32 | c.1982T>C p.I661T | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- USP32 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2
- VNN3 | c.37T>A p.F13I | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- VTN | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA3A | c.1582C>G p.H528D | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- WNT1 | c.625-2A>C p.X209_splice | Splice Site (SNP) | VAF 24/165 reads (15%) | called by muse, varscan2
- ZBBX | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB26 | c.284T>G p.F95C | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB8B | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 46/613 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZMYM3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF277 | c.500A>T p.N167I | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2
- ZNF420 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- ZNF493 | c.1130del p.S377Ifs*5 | Frame Shift Del (DEL) | VAF 36/223 reads (16%) | called by mutect2, pindel, varscan2
- ZNF736 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- ZNF786 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2
- ZNF845 | c.2159A>C p.K720T | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- AARS1 | c.2505C>T p.A835= | Silent (SNP) | VAF 42/814 reads (5%) | catalogued as rs769571173, COSV55747364; ClinVar: uncertain significance; called by muse, mutect2
- ADH5 | c.618A>T p.A206= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.864G>A p.E288= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as COSV100125569; called by muse, mutect2, varscan2
- ASCC3 | c.5997G>T p.L1999= | Silent (SNP) | VAF 33/410 reads (8%) | catalogued as COSV64974410; called by muse, mutect2
- ASPG | c.417C>T p.L139= | Silent (SNP) | VAF 15/224 reads (7%) | catalogued as rs1254709151; called by muse, mutect2
- ATP1A2 | c.561C>T p.D187= | Silent (SNP) | VAF 28/359 reads (8%) | catalogued as rs760347405; called by muse, mutect2
- BTBD1 | c.1050A>G p.R350= | Silent (SNP) | VAF 13/247 reads (5%) | called by muse, mutect2
- C12orf40 | c.1959A>G p.*653= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- CEP97 | c.1686C>T p.A562= | Silent (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- CLHC1 | c.939A>T p.A313= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- CNNM4 | c.1644G>C p.P548= | Silent (SNP) | VAF 40/707 reads (6%) | catalogued as COSV65660507; called by muse, mutect2
- CNOT6L | c.264C>G p.S88= (on ENST00000504123 / NM_001286790.2; = p.S83= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- COIL | c.1455A>G p.T485= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- COL6A3 | c.456A>G p.G152= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV55106486; called by muse, mutect2
- CTNNA3 | c.1656G>T p.T552= | Silent (SNP) | VAF 53/430 reads (12%) | catalogued as COSV65617272; called by muse, mutect2, varscan2
- CXCR2 | c.624G>A p.R208= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV59281062; called by muse, mutect2
- DACT2 | c.792G>A p.L264= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- DCLK3 | c.978G>A p.K326= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- DNM3 | c.1191T>C p.G397= | Silent (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- EGFLAM | c.2124C>T p.I708= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as rs201020203; called by muse, mutect2, varscan2
- EPX | c.45C>A p.V15= | Silent (SNP) | VAF 44/664 reads (7%) | called by muse, mutect2
- ESRRB | c.1221G>T p.V407= | Silent (SNP) | VAF 36/563 reads (6%) | called by muse, mutect2
- FAM189A1 | c.180C>T p.A60= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- FAM47C | c.2436C>A p.L812= | Silent (SNP) | VAF 59/218 reads (27%) | called by muse, mutect2, varscan2
- FCRL3 | c.681C>A p.S227= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- FFAR3 | c.877A>C p.R293= | Silent (SNP) | VAF 57/473 reads (12%) | catalogued as COSV100588196; called by mutect2, varscan2
- FGD4 | c.489A>G p.P163= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- FNDC1 | c.3855C>T p.A1285= | Silent (SNP) | VAF 32/383 reads (8%) | called by muse, mutect2
- GADD45G | c.393G>A p.K131= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- GAL3ST2 | c.915G>T p.G305= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- GLI1 | c.825C>T p.C275= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs760165946; called by muse, mutect2, varscan2
- GLRA3 | c.537C>A p.P179= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs746585506; called by muse, mutect2, varscan2
- GRIN2B | c.813G>A p.A271= | Silent (SNP) | VAF 24/324 reads (7%) | catalogued as rs201732785, COSV74207906; called by muse, mutect2
- GSS | c.1242C>T p.G414= | Silent (SNP) | VAF 24/409 reads (6%) | called by muse, mutect2
- GSS | c.306T>C p.R102= | Silent (SNP) | VAF 63/647 reads (10%) | called by muse, mutect2, varscan2
- HAVCR1 | c.564G>T p.T188= | Silent (SNP) | VAF 96/581 reads (17%) | catalogued as rs759408704, COSV59399982; called by muse, mutect2, varscan2
- HMGCS2 | c.387A>G p.V129= | Silent (SNP) | VAF 53/419 reads (13%) | catalogued as rs750709310; called by muse, mutect2, varscan2
- HMX2 | c.403C>A p.R135= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1191767377, COSV100378857; called by muse, mutect2, varscan2
- HOXB2 | c.687G>T p.A229= | Silent (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- IFITM1 | c.99G>A p.V33= | Silent (SNP) | VAF 32/314 reads (10%) | called by muse, mutect2
- IGKV2D-29 | c.91C>T p.L31= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs1390544054; called by muse, mutect2, varscan2
- IGKV2D-30 | c.222T>C p.Y74= | Silent (SNP) | VAF 34/613 reads (6%) | called by muse, mutect2
- KCNH5 | c.573C>A p.I191= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as COSV59765945; called by muse, mutect2
- KIF4B | c.3453C>A p.T1151= | Silent (SNP) | VAF 30/570 reads (5%) | called by muse, mutect2
- KIF5A | c.2796C>T p.P932= | Silent (SNP) | VAF 41/613 reads (7%) | catalogued as rs1441746123; called by muse, mutect2
- LAMB2 | c.3393C>G p.L1131= | Silent (SNP) | VAF 37/756 reads (5%) | called by muse, mutect2
- LAMC3 | c.2028C>T p.P676= | Silent (SNP) | VAF 21/691 reads (3%) | catalogued as rs1342470381; called by muse, mutect2
- LCA5L | c.1227T>A p.I409= | Silent (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- LMO1 | c.45C>A p.V15= | Silent (SNP) | VAF 11/240 reads (5%) | called by muse, mutect2
- LRRC3C | c.312C>A p.V104= | Silent (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- MAGEB16 | c.324G>T p.V108= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV101303295; called by muse, mutect2, varscan2
- MAGEB17 | c.858C>T p.V286= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1022821885; called by muse, mutect2, varscan2
- MCL1 | c.477A>G p.S159= | Silent (SNP) | VAF 102/409 reads (25%) | called by muse, varscan2
- MLH1 | c.2100G>A p.Q700= | Silent (SNP) | VAF 29/458 reads (6%) | catalogued as COSV51615939; called by muse, mutect2
- MORC1 | c.2010C>A p.S670= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- MYCBPAP | c.354G>T p.L118= | Silent (SNP) | VAF 144/500 reads (29%) | called by muse, mutect2, varscan2
- MYH4 | c.4794G>C p.V1598= | Silent (SNP) | VAF 43/241 reads (18%) | called by muse, mutect2, varscan2
- NAF1 | c.42G>C p.L14= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- NDUFB8 | c.81G>A p.R27= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs768503876; called by muse, mutect2, varscan2
- OR1G1 | c.381C>T p.C127= | Silent (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- PHF3 | c.3429A>T p.V1143= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.2220G>A p.L740= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- PKP1 | c.1782A>G p.E594= | Silent (SNP) | VAF 31/514 reads (6%) | called by muse, mutect2
- PLA2G4F | c.1173G>C p.L391= | Silent (SNP) | VAF 23/195 reads (12%) | catalogued as COSV51827708; called by muse, mutect2, varscan2
- PLXNB2 | c.4572G>A p.Q1524= | Silent (SNP) | VAF 20/458 reads (4%) | called by muse, mutect2
- PPDPFL | c.255G>A p.*85= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- RAX | c.396C>G p.P132= | Silent (SNP) | VAF 39/506 reads (8%) | called by muse, mutect2
- RNASE2 | c.99C>A p.T33= | Silent (SNP) | VAF 43/221 reads (19%) | called by muse, mutect2, varscan2
- RP1 | c.3474A>G p.S1158= | Silent (SNP) | VAF 26/813 reads (3%) | catalogued as rs1283312179; called by muse, mutect2
- SIX3 | c.900G>T p.A300= | Silent (SNP) | VAF 27/336 reads (8%) | called by muse, mutect2
- SLC30A3 | c.60C>T p.D20= | Silent (SNP) | VAF 9/89 reads (10%) | called by mutect2, varscan2
- SLC4A5 | c.2526G>A p.V842= | Silent (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- SNED1 | c.2013C>A p.T671= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- SOX11 | c.129G>A p.K43= | Silent (SNP) | VAF 12/169 reads (7%) | catalogued as rs1434795736; called by muse, mutect2
- SPEG | c.7191C>T p.L2397= | Silent (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- TBX3 | c.1182G>A p.K394= (on ENST00000257566 / NM_016569.4; = p.K374= on NM_005996.4) | Silent (SNP) | VAF 47/414 reads (11%) | called by muse, mutect2, varscan2
- TDRD15 | c.3370T>C p.L1124= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- TEDC2 | c.744G>A p.Q248= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as COSV53537499; called by muse, mutect2
- TNFAIP2 | c.1953A>T p.I651= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- TRDN | c.2166A>C p.P722= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- TRIM49 | c.1222C>A p.R408= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as COSV61670731; called by muse, mutect2, varscan2
- UBR2 | c.2727G>T p.V909= | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as COSV65748560; called by muse, mutect2, varscan2
- USH2A | c.6012T>G p.S2004= | Silent (SNP) | VAF 44/360 reads (12%) | catalogued as COSV56327183; called by muse, mutect2, varscan2
- USP40 | c.2721A>T p.T907= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- VPS13D | c.6243G>T p.T2081= | Silent (SNP) | VAF 37/269 reads (14%) | called by muse, mutect2, varscan2
- WDR17 | c.3432T>C p.R1144= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- WDR87 | c.5766T>C p.S1922= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs748184112; called by muse, mutect2, varscan2
- XPO6 | c.810C>T p.L270= | Silent (SNP) | VAF 11/282 reads (4%) | catalogued as rs1261452599; called by muse, mutect2
- XYLT1 | c.51G>T p.A17= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7503C>A p.A2501= | Silent (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
- ZNF267 | c.1221A>G p.P407= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV56255955; called by muse, mutect2, varscan2
- ZNF487 | c.219A>C p.T73= | Silent (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- ABCD4 | c.1456+9G>T | Intron (SNP) | VAF 23/170 reads (14%) | catalogued as rs778938879; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288142A>C | Intron (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- AC107023.1 | n.25+9928A>C | Intron (SNP) | VAF 18/125 reads (14%) | catalogued as rs776385609; called by muse, mutect2, varscan2
- AC107023.1 | n.25+3010G>T | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, varscan2
- ADA | c.679-28T>A | Intron (SNP) | VAF 143/900 reads (16%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1380C>A | Intron (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- AL450442.1 | n.786C>A | RNA (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- AL772337.1 | n.749C>T | RNA (SNP) | VAF 26/261 reads (10%) | called by muse, mutect2
- ASIC1 | c.559-234G>T | Intron (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- BBS1 | c.831-287T>C | Intron (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- COBLL1 | c.156-35859A>C | Intron (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- ERICH3 | c.603+1582A>T | Intron (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2
- ESRP1 | chr8:94639114 A>T | 5'Flank (SNP) | VAF 52/232 reads (22%) | called by muse, mutect2, varscan2
- FBXL7 | c.740-1195G>C | Intron (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- FCRLB | c.575-202C>G | Intron (SNP) | VAF 61/314 reads (19%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3330T>C | 3'UTR (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- FREM1 | c.4857+1716G>T | Intron (SNP) | VAF 10/116 reads (9%) | called by mutect2, varscan2
- GLOD4 | c.588+28G>C | Intron (SNP) | VAF 5/69 reads (7%) | catalogued as rs1260002263; called by muse, mutect2
- HAVCR1 | c.*28C>G | 3'UTR (SNP) | VAF 96/605 reads (16%) | catalogued as COSV100208308; called by muse, mutect2, varscan2
- IGLV4-3 | c.-15G>A | 5'UTR (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- IL31RA | c.1252+21A>C | Intron (SNP) | VAF 23/410 reads (6%) | catalogued as rs1227151592; called by muse, mutect2
- LACTB2 | c.286+869G>A | Intron (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598597 G>A | 5'Flank (SNP) | VAF 45/368 reads (12%) | called by muse, mutect2, varscan2
- MEG3 | n.1150C>T | RNA (SNP) | VAF 27/207 reads (13%) | catalogued as rs1413627752; called by muse, mutect2, varscan2
- MIR205 | chr1:209429402 A>G | 5'Flank (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-598A>G | Intron (SNP) | VAF 67/335 reads (20%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120942 C>A | 3'Flank (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PHACTR4 | c.-91_-80del | 5'UTR (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- PLD1 | c.-32+17822A>C | Intron (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- PMAIP1 | c.58+302G>T | Intron (SNP) | VAF 27/207 reads (13%) | catalogued as rs113061570; called by muse, mutect2, varscan2
- POTEM | c.1409+4001C>A | Intron (SNP) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- RN7SL484P | chr15:99792270 C>A | 3'Flank (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- RPL34-DT | n.254C>T | RNA (SNP) | VAF 50/334 reads (15%) | called by muse, mutect2, varscan2
- SCN3A | c.*45T>C | 3'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- SDCBP2 | c.384+38C>G | Intron (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532592 T>C | 5'Flank (SNP) | VAF 108/416 reads (26%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1691G>A | Intron (SNP) | VAF 14/122 reads (11%) | catalogued as rs747994138; called by muse, mutect2, varscan2
- ZNF638 | c.-149del | 5'UTR (DEL) | VAF 27/175 reads (15%) | called by mutect2, pindel, varscan2
